Somatic mutation profile of tumor specimen TCGA-06-0211-01B (aliquot TCGA-06-0211-01B-01D-1491-08) from TCGA case TCGA-06-0211, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.0 years (17,515 days).
Specimen TCGA-06-0211-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cbd00d5-5f3e-4922-a2e4-850711066838.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0211-10A (Blood Derived Normal), aliquot TCGA-06-0211-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa3557b6-96ee-4e78-8c8d-e1a7d81df44a

The open-access MAF lists 64 somatic variants for this specimen: 45 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 16, Nonsense Mutation 3, Frame Shift Del 2, RNA 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.787A>C p.T263P | Missense Mutation (SNP) | VAF 86/1080 reads (8%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.236); catalogued as rs1057519829, COSV51768130; ClinVar: likely pathogenic; called by muse, mutect2
- SETBP1 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 142/383 reads (37%) | catalogued as rs1568234874, COSV56319931; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADH7 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 99/222 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs757367262, COSV52921077; called by muse, mutect2, varscan2
- CARD6 | c.1147A>G p.M383V | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV54566488; called by muse, mutect2, varscan2
- CFAP47 | c.971T>A p.I324N | Missense Mutation (SNP) | VAF 50/59 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV52885248; called by muse, mutect2, varscan2
- COL19A1 | c.691T>A p.Y231N | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV59574649; called by muse, mutect2, varscan2
- COL1A2 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749509413, COSV51956332; called by muse, mutect2, varscan2
- COL25A1 | c.1303C>G p.L435V | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs369025098, COSV67650938; called by muse, mutect2, varscan2
- CSMD1 | c.512G>A p.C171Y | Missense Mutation (SNP) | VAF 73/133 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68209616; called by muse, mutect2, varscan2
- CYP27B1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1028387024, CM1110437, COSV56985373, COSV56986329; called by muse, mutect2, varscan2
- DPT | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 118/261 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.799); catalogued as rs200956999; called by muse, mutect2, varscan2
- GABBR2 | c.1563C>G p.N521K | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52305340; called by muse, mutect2, varscan2
- GLT8D2 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.271); catalogued as rs373952967; called by muse, mutect2, varscan2
- GRM6 | c.1471G>C p.G491R | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV51442738; called by muse, varscan2
- IQSEC3 | c.2839C>A p.P947T (on ENST00000538872 / NM_001170738.2; = p.P644T on NM_015232.1) | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV58285440; called by muse, mutect2, varscan2
- ITSN1 | c.2319G>A p.W773* | Nonsense Mutation (SNP) | VAF 161/422 reads (38%) | catalogued as COSV66083475; called by muse, mutect2, varscan2
- L3MBTL1 | c.2187T>A p.D729E (on ENST00000418998 / NM_001377303.1; = p.D639E on NM_015478.7) | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV64228665; called by muse, mutect2, varscan2
- LDLRAD2 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.098); catalogued as COSV60828456; called by muse, mutect2, varscan2
- MAGEB1 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs113819941, COSV66775289; called by muse, mutect2, varscan2
- MMP17 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746751214, COSV100861980, COSV62179596; called by muse, mutect2, varscan2
- MMP3 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs782643785, COSV55406397; called by muse, mutect2, varscan2
- MUC16 | c.42245C>T p.T14082I | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.983); catalogued as COSV66692528; called by muse, mutect2, varscan2
- MYOCD | c.1060T>G p.S354A | Missense Mutation (SNP) | VAF 147/302 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV58504468; called by muse, mutect2, varscan2
- NCOR1 | c.5152C>T p.R1718W | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs373216507; called by muse, mutect2, varscan2
- NLRP13 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 121/503 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as rs1489171935, COSV100738434, COSV61622102; called by muse, mutect2, varscan2
- OPRK1 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 27/56 reads (48%) | catalogued as COSV55570940; called by muse, mutect2, varscan2
- OR14J1 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 94/243 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs769244586, COSV65845719; called by muse, mutect2, varscan2
- PCDHGB3 | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as COSV53958553; called by muse, mutect2, varscan2
- PODNL1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.184); catalogued as rs1483316106, COSV54307910; called by muse, mutect2, varscan2
- RAD51AP2 | c.641C>A p.A214D | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV67588196; called by muse, mutect2, varscan2
- REG1B | c.71A>G p.E24G | Missense Mutation (SNP) | VAF 111/291 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.488); catalogued as COSV59305945, COSV59306170; called by muse, mutect2, varscan2
- SETD2 | c.7624G>A p.E2542K | Missense Mutation (SNP) | VAF 77/155 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV57438486, COSV57438931, COSV57446878; called by muse, mutect2, varscan2
- SIGLEC10 | c.995A>G p.Q332R | Missense Mutation (SNP) | VAF 52/295 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.3); catalogued as COSV59482348; called by muse, mutect2, varscan2
- STARD3NL | c.38C>A p.T13N | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV50518531; called by muse, mutect2, varscan2
- SYT16 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs773454309, COSV70856997; called by muse, mutect2, varscan2
- TLR4 | c.1257G>C p.L419F (on ENST00000355622 / NM_138554.5; = p.L379F on NM_003266.4) | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.473); catalogued as COSV62923395; called by muse, mutect2, varscan2
- TMOD3 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.107); catalogued as COSV57943989, COSV57945854; called by muse, mutect2, varscan2
- TMTC4 | c.356C>T p.S119F (on ENST00000376234 / NM_001350577.2; = p.S138F on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV60892414; called by muse, mutect2, varscan2
- TRIM29 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 85/197 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.165); catalogued as rs769401812, COSV59280694; called by muse, mutect2, varscan2
- UGT1A1 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs370790922; called by muse, mutect2, varscan2
- YOD1 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60006359; called by muse, mutect2, varscan2
- ZNF254 | c.1928C>G p.S643W | Missense Mutation (SNP) | VAF 77/318 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV61642790; called by muse, mutect2, varscan2
- IGKV1D-42 | c.129C>G p.I43M | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- KRT24 | c.224del p.G75Vfs*81 | Frame Shift Del (DEL) | VAF 67/156 reads (43%) | called by mutect2, pindel, varscan2
- RPL5 | c.175_176del p.D59Yfs*53 | Frame Shift Del (DEL) | VAF 18/79 reads (23%) | called by pindel, varscan2
- ABI3 | c.714C>A p.P238= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV56800335; called by muse, mutect2, varscan2
- CLIC5 | c.687G>A p.T229= (on ENST00000185206 / NM_001370649.1; = p.T70= on NM_016929.5) | Silent (SNP) | VAF 107/251 reads (43%) | catalogued as rs1192732085, COSV51759019; called by muse, mutect2, varscan2
- DPP10 | c.1911G>A p.L637= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV59690125; called by muse, mutect2, varscan2
- FLG | c.2889T>C p.S963= | Silent (SNP) | VAF 275/602 reads (46%) | catalogued as COSV64242540; called by muse, mutect2, varscan2
- HCN1 | c.1623T>A p.I541= | Silent (SNP) | VAF 60/142 reads (42%) | catalogued as COSV57513650; called by muse, mutect2, varscan2
- HDAC9 | c.2337C>A p.P779= | Silent (SNP) | VAF 78/289 reads (27%) | catalogued as COSV67774301; called by muse, mutect2, varscan2
- ITGAM | c.198C>T p.C66= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs369704125, COSV54938777; called by muse, varscan2
- KCNQ5 | c.2337C>T p.D779= | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as rs779824484, COSV59661950; called by muse, mutect2, varscan2
- KIR2DL4 | c.1011G>T p.V337= (on ENST00000396284; = p.V263= on NM_001080770.2) | Silent (SNP) | VAF 213/742 reads (29%) | catalogued as COSV58491490; called by muse, mutect2, varscan2
- LILRB5 | c.621G>A p.S207= | Silent (SNP) | VAF 56/209 reads (27%) | catalogued as rs144716655, COSV100300498; called by muse, mutect2, varscan2
- MINDY1 | c.99G>A p.E33= | Silent (SNP) | VAF 97/446 reads (22%) | catalogued as COSV56499042; called by muse, mutect2, varscan2
- MRPS7 | c.267A>T p.P89= | Silent (SNP) | VAF 10/217 reads (5%) | catalogued as COSV55453558; called by muse, mutect2
- OTOP1 | c.330C>T p.Y110= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs764769166, COSV56396040; called by muse, mutect2, varscan2
- RFX4 | c.1497G>A p.L499= (on ENST00000392842 / NM_213594.3; = p.L405= on NM_032491.6) | Silent (SNP) | VAF 93/225 reads (41%) | catalogued as COSV57576235; called by muse, mutect2, varscan2
- RSPH10B | c.2301C>G p.V767= | Silent (SNP) | VAF 165/1255 reads (13%) | catalogued as rs749626793, COSV58074125; called by muse, mutect2, varscan2
- UGT2B4 | c.534C>T p.Y178= | Silent (SNP) | VAF 57/128 reads (45%) | catalogued as rs370531105; called by muse, mutect2, varscan2
- GLOD4 | chr17:782629 del CCAGCACCTGGG | 5'Flank (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel, varscan2
- MIR16-1 | n.27A>G | RNA (SNP) | VAF 50/114 reads (44%) | called by muse, mutect2, varscan2
- RPL31P57 | n.348del | RNA (DEL) | VAF 11/24 reads (46%) | catalogued as rs1567988553; called by mutect2, pindel, varscan2
